TARGET case TARGET-30-PAPUJU — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Adrenal gland. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/14fd643d-a114-5d7b-8340-a7800c31434d

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 2 years; Vital status: Alive.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; ICD-10 code: C74.9; Tissue or organ of origin: Adrenal gland, NOS; Classification of tumor: primary; Age at diagnosis: 2.6 years (954 days); Year of diagnosis: 2006; Days to last follow up: 3,898 days (10.7 years); Cog neuroblastoma risk group: High Risk; INSS stage: Stage 4.
   Pathology details: Necrosis percent: 10; Percent tumor nuclei: 60.
   Treatment given: Protocol identifier: ANBL00B1.

Follow-up (1 entry)
- Days to follow up: 3,898 days (10.7 years); Event-free: no event (relapse, second malignancy or death) recorded through day 3,898; Year of follow up: 2017.

Molecular and laboratory tests
- MYCN amplification: Not Amplified.
- Test: Abnormal, NOS; Ploidy: Hyperdiploid.

Biospecimens (2 samples)
- Sample TARGET-30-PAPUJU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PAPUJU-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_NBL_ClinicalData_Discovery_20230523.xlsx (sheet Clinical Data):
- First Event: Censored
- Overall Survival Time in Days: 3898
- Ploidy: Hyperdiploid (DI>1)
- Ploidy Value: 1.08
- ICDO Description: Adrenal gland, NOS Suprarenal gland Adrenal, NOS
- Percent Tumor v/s Stroma: 60/40
